Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5281, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5281-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

Brain, left frontotemporal, excision: Grade 3 (of 4) oligoastrocytoma, astrocytic predominant, (WHO, grade III).

Seen in consultation with [REDACTED]

Results of FISH studies for 1p and 19q deletion will be reported as an addendum.

TCGA-DB-5281

ADDENDA:

1p and 19q FISH studies were performed on cells within paraffin sections from tumor. Two hybridizations were performed: one with a 19q probe/control 19p pair and one with a 1p probe/control 1q pair. The 19q and 1p probes mapped to the regions that are commonly deleted in gliomas. The 19q to 19p probe ratio was 1.02. The 1p to 1q probe ratio was 0.87. For both probes, the normal ratio is approximately 1. Any ratio less than 0.80 is consistent with deletion of the chromosomal region of interest.

there was no evidence of deletion of 1p or 19q. However, approximately 70% of the cells had 3-4 copies of the 1p, 1q, 19p, and 19q probes. Similar results have been observed in other glioma specimens with gain of chromosomes 1 and 19. The results may also be consistent with tumor tetraploidy or aneuploidy.

This test was developed and its performance characteristics determined by Laboratory Medicine and Pathology, [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration, and is to

[page 2 of 2]
be used as an adjunct to existing clinical and pathological information. This test does not rule out other chromosome anomalies.

AMENDMENTS:

Revision Description: Change Sp & 1Yq to 1p and 19q.

...Original Diagnosis...

Brain, left frontotemporal, excision: Grade 3 (of 4) oligoastrocytoma, astrocytic predominant, (WHO, grade III).

Results of FISH studies for for Sp & 1Yq deletion will be reported as an addendum.

*:

Preliminary Frozen Section Consultation:

Brain, left frontotemporal, excision: High grade glioma. HOLD for perms.

Gross Description:

Tissue from brain (left frontotemporal No.1 - 0.4 cm, No.2 - 7.5 x 6.0 x 1.5 cm, No.3 - 6.5 x 5.0 x 2.0 cm, No.4 - 6.0 x 2.0 x 1.0 cm).

Block Summary:

Part A: LT FRONTAL TEMPORAL TUMOR

Part B: LT FRONTAL TEMPORAL TUMOR #2

- 1 lt frontal temporal tx
- 2 lt frontal temporal tx
- 3 lt frontal temporal tx
- 4 lt frontal temporal tx
- 5 lt frontal temporal tx
- 6 lt frontal temporal tx
- 7 lt frontal temporal tx
- 8 lt frontal temporal tx
- 9 lt frontal temporal tx
- 10 lt frontal temporal tx
- 11 lt frontal temporal tx

Part C: LEFT FRONTOTEMPORAL

- 1 lt frontotemporal tx
- 2 lt frontotemporal tx
- 3 lt frontotemporal tx
- 4 lt frontotemporal tx
- 5 lt frontotemporal tx
- 6 lt frontotemporal tx
- 7 lt frontotemporal tx

Part D: LEFT FRONTOTEMPORAL

- 1 lt frontotemporal tx

Source: NCI Genomic Data Commons file 714df01f-9305-401e-bf98-3e8f7624020d (TCGA-DB-5281.40462852-7DC3-4A3F-A4F3-7CD5A4ADBD0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).